Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XU, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XU-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Total organ resection – left breast

Unit in charge:

Physician in charge:

Material collected on: (

Material received on: (

Expected time of examination: up to 8 working days

Clinical diagnosis: Bifocal cancer of the left breast. Simple mastectomy.

100-0-3

Carcinoma, infiltrating duct, NOS 85009
Site: breast, NOS 050.9
for 4/13/11

Examination performed on:

Results of immunohistochemical examination:

Focus marked as R1:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in 10-75% of neoplastic cell nuclei.

HER2 protein stained using rabbit antibody Ventana PATHWAY HER-2/neu (4B5). Negative reaction in invasive cancerous cells (Score = 1+)

Focus marked as R2:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in 10-75% of neoplastic cell nuclei.

HER2 protein stained using rabbit antibody Ventana PATHWAY HER-2/neu (4B5). Negative reaction in invasive cancerous cells (Score = 1+)

Compliance valid.

Examination performed on:

Macroscopic description:

Carcinoma ductale bifocale - NHG2 (3 + 2+1:0 mitoses/ 10 HPF, visual area diameter: 0,55 mm).

Carcinoma ductale in situ (DCIS) within the tumours (solid and cribrate type with high nuclear atypia, and point and comedo necrosis, 10% of the tumour areas).

Invasio carcinomatosa vasorum.

In situ lesion of the type cancerisatio lobulorum.

Mamilla sine laesionibus.

Glandular tissue showing parenchymal atrophy.

IHPAA Discrepancy		☒

[page 2 of 2]
Examination No.:

Patient: **XXX**

PESEL: **XXX**

Gender: **F**

Examination performed on: -----

Histopathological diagnosis:

Carcinoma ducale bifocale invasivum et in situ mammae sinistrae. Invasive bifocal ductal carcinoma and carcinoma in situ of the left breast (NHG2, pT1c, pNO (SN)). Invasio carcinomatosa vasorum. Vascular invasion.

Compliance valida:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 6e04437f-7c30-4352-ad97-26c95b2ce0e0 (TCGA-D8-A1XU.845F8FCF-CF3C-4CEF-B673-A57DE626939C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).